Somatic mutation profile of tumor specimen HCM-BROD-0870-C43-06B (aliquot HCM-BROD-0870-C43-06B-11D-A881-36) from HCMI case HCM-BROD-0870-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 50.3 years (18,388 days).
Specimen HCM-BROD-0870-C43-06B: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7418a00-118b-4084-b953-7e79fb4cc191.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0870-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0870-C43-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e4357c7-4688-4752-bb57-7b532c57510a

The open-access MAF lists 238 somatic variants for this specimen: 148 protein-altering or splice-affecting, 77 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 137, Silent 77, Intron 9, Splice Region 4, Nonsense Mutation 3, Frame Shift Del 2, RNA 2, 5'UTR 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 436/543 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CNOT9 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 137/399 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen benign (0.086); catalogued as rs1057519955, COSV55299045; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DNAH5 | c.10615C>T p.R3539C | Missense Mutation (SNP) | VAF 207/515 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1304504006, CM091938, COSV54205813; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANKRD30A | c.1787G>A p.G596E (on ENST00000611781; = p.G540E on NM_052997.2) | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.938); catalogued as COSV64616394; called by muse, mutect2, varscan2
- ANO9 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 242/685 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as rs779445613, COSV60449118; called by muse, mutect2, varscan2
- ARFGAP3 | c.1100C>T p.S367F | Missense Mutation (SNP) | VAF 122/398 reads (31%) | SIFT tolerated (1); PolyPhen possibly damaging (0.577); catalogued as COSV54314814; called by muse, mutect2, varscan2
- ARHGEF28 | c.553C>T p.L185F | Missense Mutation (SNP) | VAF 131/454 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.896); catalogued as rs760410003, COSV55256428; called by muse, mutect2, varscan2
- ASTN1 | c.3648G>A p.R1216= | Splice Region (SNP) | VAF 124/314 reads (39%) | catalogued as COSV62490720; called by muse, mutect2, varscan2
- ASXL3 | c.4894G>C p.E1632Q | Missense Mutation (SNP) | VAF 147/486 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.307); catalogued as COSV52462181, COSV99325833; called by muse, mutect2, varscan2
- ATP2C2 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 141/392 reads (36%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.492); catalogued as rs1402622840, COSV52294177; called by muse, mutect2, varscan2
- ATP6V1C2 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 152/497 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); catalogued as COSV55364498; called by muse, mutect2, varscan2
- ATRX | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 172/531 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.115); catalogued as rs782313786, COSV64871675; called by muse, mutect2, varscan2
- BPIFB4 | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 282/707 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64952570; called by muse, mutect2, varscan2
- BRCC3 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 93/295 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV57462323; called by muse, mutect2, varscan2
- CCDC178 | c.1436C>A p.S479Y | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.773); catalogued as rs765850680; called by muse, mutect2, varscan2
- CDH18 | c.2178C>A p.D726E | Missense Mutation (SNP) | VAF 245/616 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs955129072; called by muse, mutect2, varscan2
- CDH6 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 107/418 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs1211213609; called by muse, mutect2, varscan2
- CDH9 | c.2197G>A p.D733N | Missense Mutation (SNP) | VAF 130/508 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50258336; called by muse, varscan2
- COL5A3 | c.5089C>G p.R1697G | Missense Mutation (SNP) | VAF 121/344 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.494); catalogued as rs568686157, COSV53410819, COSV53416701, COSV53421862; called by muse, mutect2, varscan2
- DMD | c.9197C>T p.S3066L | Missense Mutation (SNP) | VAF 131/432 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs128626254, CM940363, COSV58891045; called by muse, mutect2, varscan2
- DSG3 | c.2009G>A p.G670E | Missense Mutation (SNP) | VAF 104/348 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.434); catalogued as rs1243605673, COSV57128501, COSV99934489; called by muse, mutect2, varscan2
- ERN2 | c.570G>A p.M190I | Missense Mutation (SNP) | VAF 125/364 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1292748541; called by muse, mutect2, varscan2
- FMO2 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 142/571 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV99269316; called by muse, mutect2, varscan2
- FMO2 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 140/575 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs144453031; called by muse, mutect2, varscan2
- FTCD | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 330/496 reads (67%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as rs538473571; called by muse, mutect2, varscan2
- FZR1 | c.424G>A p.G142S | Missense Mutation (SNP) | VAF 181/509 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1393597379; called by muse, mutect2, varscan2
- GABRA3 | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 201/558 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs1405808499, COSV64795525; called by muse, mutect2, varscan2
- GIMAP8 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 675/852 reads (79%) | SIFT tolerated (0.28); PolyPhen benign (0.025); catalogued as COSV56229625; called by muse, mutect2, varscan2
- GLB1L2 | c.1431T>C p.G477= | Splice Region (SNP) | VAF 100/375 reads (27%) | catalogued as rs267602789; called by muse, mutect2, varscan2
- GLRB | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 133/414 reads (32%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.989); catalogued as COSV52414330; called by muse, mutect2, varscan2
- GRID2IP | c.3362C>T p.S1121F | Missense Mutation (SNP) | VAF 146/339 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as COSV101474879, COSV70693595; called by muse, mutect2, varscan2
- HERC2 | c.5916G>C p.Q1972H | Missense Mutation (SNP) | VAF 191/532 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as rs1174854629; called by muse, mutect2, varscan2
- HMG20A | c.949A>G p.M317V | Missense Mutation (SNP) | VAF 130/390 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as rs374136790; called by muse, mutect2, varscan2
- IGKV1OR2-108 | c.155G>A p.S52N | Missense Mutation (SNP) | VAF 72/251 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs781217895; called by muse, mutect2, varscan2
- IGSF9B | c.2890G>A p.G964S | Missense Mutation (SNP) | VAF 215/714 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as rs756662862; called by muse, mutect2, varscan2
- ING1 | c.119C>A p.S40Y | Missense Mutation (SNP) | VAF 243/773 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.407); catalogued as COSV58168619; called by muse, mutect2, varscan2
- INHBA | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 136/369 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99637312; called by muse, mutect2, varscan2
- IRF2 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 140/447 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101165834; called by muse, mutect2, varscan2
- IRS4 | c.3034G>A p.E1012K | Missense Mutation (SNP) | VAF 284/759 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as rs369073955; called by muse, mutect2, varscan2
- KLK12 | c.536G>A p.R179K | Missense Mutation (SNP) | VAF 175/528 reads (33%) | SIFT tolerated (0.72); PolyPhen benign (0.055); catalogued as COSV51578971; called by muse, mutect2, varscan2
- KRT79 | c.1080C>G p.N360K | Missense Mutation (SNP) | VAF 160/432 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.026); catalogued as COSV57938876; called by muse, mutect2, varscan2
- LCE3B | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 126/207 reads (61%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.018); catalogued as rs1192495182; called by muse, mutect2, varscan2
- MADD | c.2410C>T p.R804W | Missense Mutation (SNP) | VAF 80/243 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as rs755575127; called by muse, mutect2, varscan2
- MAEL | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 84/262 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63112269; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1966C>T p.P656S | Missense Mutation (SNP) | VAF 199/622 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50495097; called by muse, mutect2, varscan2
- MDGA1 | c.2725G>A p.V909I | Missense Mutation (SNP) | VAF 238/979 reads (24%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.989); catalogued as rs372901709; called by muse, mutect2, varscan2
- MORN3 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 177/479 reads (37%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.89); catalogued as rs755118040; called by muse, mutect2, varscan2
- MYH2 | c.2602G>A p.E868K | Missense Mutation (SNP) | VAF 84/485 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.052); catalogued as rs267604724, COSV55432215; called by muse, mutect2, varscan2
- N4BP3 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 280/604 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as rs747842127; called by muse, mutect2, varscan2
- NIBAN3 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 174/542 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.616); catalogued as rs1399353412; called by muse, mutect2, varscan2
- NLRP11 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 109/312 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs561555803, COSV64086215; called by muse, mutect2, varscan2
- NOMO2 | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 41/327 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs453341; called by muse, mutect2
- NOS2 | c.2273C>T p.S758F | Missense Mutation (SNP) | VAF 157/399 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.396); catalogued as rs749457124, COSV58223952; called by muse, mutect2, varscan2
- NRK | c.4532G>A p.R1511Q | Missense Mutation (SNP) | VAF 122/382 reads (32%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.665); catalogued as rs1310620401, COSV54592660; called by muse, mutect2, varscan2
- OLFML2B | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 72/408 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.23); catalogued as rs529486618, COSV54197643; called by muse, mutect2, varscan2
- OR4A5 | c.154T>C p.S52P | Missense Mutation (SNP) | VAF 174/546 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.046); catalogued as COSV60522194; called by muse, mutect2, varscan2
- OR5T3 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 179/538 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as rs773056706, COSV57379984; called by muse, mutect2, varscan2
- PKN3 | c.2473G>A p.A825T | Missense Mutation (SNP) | VAF 91/527 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as COSV52575211; called by muse, mutect2, varscan2
- PLCH1 | c.2543C>T p.S848F (on ENST00000340059 / NM_001130960.2; = p.S860F on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 113/298 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58188602; called by muse, mutect2, varscan2
- RAX2 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 255/847 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs573892963; called by muse, mutect2, varscan2
- RESP18 | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 134/328 reads (41%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs1014650014; called by muse, mutect2, varscan2
- RREB1 | c.3325C>T p.P1109S | Missense Mutation (SNP) | VAF 457/939 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs866781104; called by muse, mutect2, varscan2
- SCN10A | c.3090G>A p.Q1030= | Splice Region (SNP) | VAF 112/320 reads (35%) | catalogued as COSV101479590; called by muse, mutect2, varscan2
- SERPINI2 | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 71/283 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.767); catalogued as rs1179630854, COSV52987808; called by muse, mutect2, varscan2
- SEZ6L | c.2464C>T p.P822S | Missense Mutation (SNP) | VAF 186/582 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.942); catalogued as COSV99961652; called by muse, mutect2, varscan2
- SLC37A1 | c.1412C>T p.T471M | Missense Mutation (SNP) | VAF 133/394 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs771928444, COSV61402785; called by muse, mutect2, varscan2
- SLC38A1 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 96/225 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0.147); catalogued as rs267603474, COSV67065149; called by muse, mutect2, varscan2
- SLC6A14 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 138/478 reads (29%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as rs782188754; called by muse, mutect2, varscan2
- SLC9A4 | c.1810C>T p.R604W | Missense Mutation (SNP) | VAF 89/274 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs761269889, COSV54832151; called by muse, mutect2, varscan2
- SLFN11 | c.2258C>T p.S753L | Missense Mutation (SNP) | VAF 107/254 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as rs1354357753; called by muse, mutect2, varscan2
- SMPD3 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 275/779 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs778977627; called by muse, mutect2, varscan2
- SPATA19 | c.393G>A p.M131I | Missense Mutation (SNP) | VAF 202/686 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1465997494; called by muse, mutect2
- TACC2 | c.4783C>T p.P1595S | Missense Mutation (SNP) | VAF 183/427 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as rs375588375; called by muse, mutect2, varscan2
- THRB | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 166/514 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.156); catalogued as rs1273720385, COSV54982017; called by muse, mutect2, varscan2
- TMEM200A | c.1010C>T p.S337F | Missense Mutation (SNP) | VAF 144/326 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV51655530; called by muse, mutect2, varscan2
- TTN | c.12496G>A p.E4166K (on ENST00000591111; = p.E4120K on NM_003319.4) | Missense Mutation (SNP) | VAF 155/451 reads (34%) | catalogued as rs776176473; called by muse, mutect2, varscan2
- VCX | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 168/1256 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs1569093120; called by muse, varscan2
- VEGFC | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 108/324 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.283); catalogued as COSV54599534; called by muse, mutect2, varscan2
- WDFY4 | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 162/332 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.384); catalogued as rs148176877, COSV57427113; called by muse, mutect2, varscan2
- ZNF75A | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 159/492 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.121); catalogued as rs376917976; called by muse, mutect2, varscan2
- ZNF768 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 254/771 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.038); catalogued as rs1360527144; called by muse, mutect2, varscan2
- ACSM3 | c.402G>A p.W134* | Nonsense Mutation (SNP) | VAF 129/373 reads (35%) | called by muse, mutect2, varscan2
- ADGRE5 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 134/357 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- AL592490.1 | c.1375C>T p.P459S | Missense Mutation (SNP) | VAF 132/426 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- ARPP21 | c.203G>A p.S68N | Missense Mutation (SNP) | VAF 123/388 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ASXL3 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 146/442 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- ATP4A | c.15G>A p.E5= | Splice Region (SNP) | VAF 165/530 reads (31%) | called by muse, mutect2, varscan2
- C2CD3 | c.1640C>T p.T547I | Missense Mutation (SNP) | VAF 151/463 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- C2orf16 | c.5068G>A p.E1690K | Missense Mutation (SNP) | VAF 99/305 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- CAPRIN2 | c.1913T>C p.V638A | Missense Mutation (SNP) | VAF 86/210 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- CCDC136 | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 433/529 reads (82%) | SIFT tolerated (0.66); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- COL5A1 | c.1771C>T p.Q591* | Nonsense Mutation (SNP) | VAF 142/468 reads (30%) | called by muse, mutect2, varscan2
- COX7B2 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 119/334 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- DCBLD2 | c.89T>A p.L30H | Missense Mutation (SNP) | VAF 232/763 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- DLL1 | c.338G>C p.G113A | Missense Mutation (SNP) | VAF 155/378 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- DSCAM | c.5582G>T p.S1861I | Missense Mutation (SNP) | VAF 354/534 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ELOA2 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 169/622 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- ELOA3D | c.1027C>G p.R343G | Missense Mutation (SNP) | VAF 149/1113 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- EXT2 | c.1699C>T p.P567S (on ENST00000343631; = p.P600S on NM_000401.3) | Missense Mutation (SNP) | VAF 107/367 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- F12 | c.326C>A p.T109N | Missense Mutation (SNP) | VAF 216/478 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- FCHO1 | c.2320T>A p.Y774N | Missense Mutation (SNP) | VAF 292/803 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- FUBP3 | c.1210A>G p.R404G | Missense Mutation (SNP) | VAF 35/784 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.057); called by muse, mutect2
- FZR1 | c.425G>A p.G142D | Missense Mutation (SNP) | VAF 182/514 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GALNT2 | c.1360A>G p.T454A | Missense Mutation (SNP) | VAF 147/570 reads (26%) | SIFT tolerated (0.78); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GCN1 | c.3302C>T p.T1101I | Missense Mutation (SNP) | VAF 143/360 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.075); called by muse, varscan2
- GUCA2A | c.194T>C p.V65A | Missense Mutation (SNP) | VAF 129/444 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HCAR2 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 72/590 reads (12%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.054); called by muse, varscan2
- IL13RA1 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 156/565 reads (28%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- JAK1 | c.1584del p.K528Nfs*13 | Frame Shift Del (DEL) | VAF 215/499 reads (43%) | called by mutect2, pindel, varscan2
- KMT2A | c.4218G>C p.K1406N | Missense Mutation (SNP) | VAF 43/200 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- LPL | c.1052G>A p.G351E | Missense Mutation (SNP) | VAF 133/437 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- MGAM | c.1442C>T p.S481L | Missense Mutation (SNP) | VAF 355/450 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- MMP25 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 241/682 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MUC12 | c.13493C>G p.T4498S (on ENST00000379442; = p.T4355S on NM_001164462.1) | Missense Mutation (SNP) | VAF 311/3646 reads (9%) | SIFT deleterious (0.01); called by muse, mutect2
- MVP | c.2244_2250dup p.L751Tfs*6 | Frame Shift Ins (INS) | VAF 113/408 reads (28%) | called by mutect2, varscan2
- NEFH | c.1577C>T p.S526L | Missense Mutation (SNP) | VAF 239/649 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- NFE2L1 | c.1354C>T p.L452F | Missense Mutation (SNP) | VAF 130/575 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOX1 | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 178/527 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- NRK | c.1897A>G p.I633V | Missense Mutation (SNP) | VAF 215/667 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR1I1 | c.409T>C p.C137R | Missense Mutation (SNP) | VAF 167/566 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR8G5 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 109/243 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PID1 | c.181G>A p.E61K (on ENST00000354069 / NM_001330156.1; = p.E59K on NM_017933.5) | Missense Mutation (SNP) | VAF 113/408 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- PLEKHB2 | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 26/122 reads (21%) | called by muse, mutect2, varscan2
- PPM1G | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 102/278 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- PPP1R32 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 152/394 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PROM1 | c.784+1G>C p.X262_splice | Splice Site (SNP) | VAF 33/276 reads (12%) | called by muse, mutect2, varscan2
- PRPF4 | c.1244C>A p.S415Y (on ENST00000374198 / NM_001322267.2; = p.S416Y on NM_004697.5) | Missense Mutation (SNP) | VAF 84/269 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PRR30 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 214/625 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTGDS | c.223G>A p.G75S | Missense Mutation (SNP) | VAF 241/764 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- PXDNL | c.495C>G p.S165R | Missense Mutation (SNP) | VAF 38/358 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- RADIL | c.3005G>A p.G1002E | Missense Mutation (SNP) | VAF 58/382 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RANBP3L | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 129/415 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, varscan2
- RAX2 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 257/855 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBMXL2 | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 194/628 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- RFPL1 | c.871G>A p.G291S | Missense Mutation (SNP) | VAF 138/432 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- RYR2 | c.8675T>G p.I2892S | Missense Mutation (SNP) | VAF 176/425 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- SEMG2 | c.704A>C p.Q235P | Missense Mutation (SNP) | VAF 174/560 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SMAP1 | c.1162C>T p.P388S (on ENST00000370455 / NM_001044305.3; = p.P361S on NM_021940.5) | Missense Mutation (SNP) | VAF 114/410 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- STXBP5L | c.2330A>T p.K777I | Missense Mutation (SNP) | VAF 168/459 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TNS3 | c.3574G>C p.G1192R | Missense Mutation (SNP) | VAF 163/434 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TPTE2 | c.1225G>A p.D409N (on ENST00000400230 / NM_199254.2; = p.D332N on NM_130785.3) | Missense Mutation (SNP) | VAF 62/257 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TRPM7 | c.4294G>A p.G1432R | Missense Mutation (SNP) | VAF 129/349 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- UBR4 | c.13651A>C p.K4551Q | Missense Mutation (SNP) | VAF 156/458 reads (34%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- VGLL1 | c.538del p.R180Vfs*16 | Frame Shift Del (DEL) | VAF 240/842 reads (29%) | called by mutect2, pindel, varscan2
- VWDE | c.2226G>A p.M742I | Missense Mutation (SNP) | VAF 76/442 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ZGRF1 | c.5161A>G p.S1721G | Missense Mutation (SNP) | VAF 86/300 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZMIZ1 | c.1582C>T p.P528S | Missense Mutation (SNP) | VAF 223/480 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ZNF641 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 196/484 reads (40%) | SIFT tolerated (0.83); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- A2ML1 | c.1992G>A p.S664= | Silent (SNP) | VAF 60/345 reads (17%) | catalogued as rs765976469, COSV55285501; called by muse, mutect2, varscan2
- ACAN | c.2538C>T p.P846= | Silent (SNP) | VAF 269/767 reads (35%) | catalogued as rs764257241; called by muse, mutect2
- ACAN | c.7638C>T p.T2546= (on ENST00000560601 / NM_001369268.1; = p.T2409= on NM_001135.3) | Silent (SNP) | VAF 92/330 reads (28%) | catalogued as COSV99053970; called by muse, mutect2, varscan2
- ADAT1 | c.1137G>A p.A379= | Silent (SNP) | VAF 93/556 reads (17%) | catalogued as rs531442684, COSV100329335; called by muse, mutect2, varscan2
- ADGRF1 | c.2298C>T p.L766= | Silent (SNP) | VAF 197/808 reads (24%) | catalogued as rs779017189, COSV51947500; called by muse, mutect2, varscan2
- ADH1A | c.876C>T p.I292= | Silent (SNP) | VAF 138/484 reads (29%) | catalogued as rs1262171039, COSV52924492; called by muse, mutect2, varscan2
- ANGPT1 | c.366C>T p.N122= | Silent (SNP) | VAF 167/863 reads (19%) | called by muse, mutect2, varscan2
- ANKFN1 | c.3295C>T p.L1099= (on ENST00000653862; = p.L952= on NM_001365758.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 238/518 reads (46%) | catalogued as rs1213456893; called by muse, mutect2, varscan2
- AP1M2 | c.714C>T p.F238= | Silent (SNP) | VAF 197/531 reads (37%) | called by muse, mutect2, varscan2
- AWAT2 | c.897C>T p.I299= | Silent (SNP) | VAF 180/568 reads (32%) | catalogued as rs1410400116, COSV52143766, COSV99339792; called by muse, mutect2, varscan2
- BEST3 | c.1779G>A p.P593= | Silent (SNP) | VAF 87/424 reads (21%) | catalogued as rs1346224457; called by muse, mutect2, varscan2
- C1GALT1C1L | c.543G>A p.V181= | Silent (SNP) | VAF 135/360 reads (38%) | catalogued as rs752004306; called by muse, mutect2, varscan2
- CCDC102B | c.693T>C p.G231= | Silent (SNP) | VAF 157/303 reads (52%) | called by muse, mutect2, varscan2
- CFAP47 | c.9171G>A p.L3057= | Silent (SNP) | VAF 66/217 reads (30%) | called by muse, mutect2, varscan2
- CLEC4M | c.942C>T p.F314= | Silent (SNP) | VAF 83/280 reads (30%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.720G>A p.L240= | Silent (SNP) | VAF 336/410 reads (82%) | catalogued as COSV62242565; called by muse, varscan2
- COLEC12 | c.1224G>A p.S408= | Silent (SNP) | VAF 183/483 reads (38%) | catalogued as rs773317089, COSV68371408; called by muse, mutect2, varscan2
- DENND6B | c.1467C>T p.F489= | Silent (SNP) | VAF 153/463 reads (33%) | called by muse, mutect2, varscan2
- DNAH7 | c.11982G>A p.T3994= | Silent (SNP) | VAF 184/510 reads (36%) | catalogued as rs781492764, COSV56753497; called by muse, mutect2, varscan2
- DNAH8 | c.1755C>T p.A585= | Silent (SNP) | VAF 144/301 reads (48%) | called by muse, mutect2, varscan2
- EIF4E3 | c.292C>T p.L98= | Silent (SNP) | VAF 109/339 reads (32%) | catalogued as rs1353322621; called by muse, mutect2, varscan2
- ELOA3B | c.858C>T p.S286= | Silent (SNP) | VAF 224/2818 reads (8%) | called by muse, mutect2
- EPO | c.147C>T p.A49= | Silent (SNP) | VAF 65/841 reads (8%) | catalogued as rs149877548; called by muse, mutect2
- FGF4 | c.396C>T p.A132= | Silent (SNP) | VAF 227/697 reads (33%) | called by muse, mutect2, varscan2
- GART | c.736C>T p.L246= | Silent (SNP) | VAF 58/307 reads (19%) | catalogued as rs201437866, COSV63114432; called by muse, mutect2, varscan2
- GLRA1 | c.519C>T p.F173= | Silent (SNP) | VAF 122/216 reads (56%) | catalogued as COSV99199722; called by muse, mutect2, varscan2
- GRXCR1 | c.85C>T p.L29= | Silent (SNP) | VAF 167/536 reads (31%) | catalogued as COSV101295654, COSV67670157; called by muse, mutect2, varscan2
- GYS1 | c.1320C>T p.F440= | Silent (SNP) | VAF 104/340 reads (31%) | called by muse, mutect2, varscan2
- HIBCH | c.213G>A p.Q71= | Silent (SNP) | VAF 97/311 reads (31%) | called by muse, mutect2, varscan2
- INTS1 | c.2184C>T p.L728= | Silent (SNP) | VAF 137/389 reads (35%) | catalogued as rs201374652; called by muse, mutect2, varscan2
- JDP2 | c.237G>A p.R79= | Silent (SNP) | VAF 135/269 reads (50%) | called by muse, mutect2, varscan2
- KIAA2026 | c.930C>T p.F310= | Silent (SNP) | VAF 125/269 reads (46%) | catalogued as rs759835110; called by muse, mutect2, varscan2
- KIR3DL2 | c.321G>A p.S107= | Silent (SNP) | VAF 11/184 reads (6%) | catalogued as rs370791268; called by muse, mutect2
- KLHL17 | c.1083C>T p.A361= | Silent (SNP) | VAF 208/669 reads (31%) | catalogued as rs1450432568; called by muse, mutect2, varscan2
- KRT4 | c.985C>T p.L329= | Silent (SNP) | VAF 75/170 reads (44%) | catalogued as rs1490353058, COSV53409404; called by muse, mutect2, varscan2
- LACRT | c.186G>A p.E62= | Silent (SNP) | VAF 151/450 reads (34%) | catalogued as COSV99143905; called by muse, mutect2, varscan2
- LIMD1 | c.1278G>A p.R426= | Silent (SNP) | VAF 115/619 reads (19%) | called by muse, mutect2, varscan2
- LRP12 | c.2319T>C p.V773= | Silent (SNP) | VAF 529/841 reads (63%) | called by muse, mutect2, varscan2
- LRRC31 | c.627C>T p.S209= | Silent (SNP) | VAF 124/411 reads (30%) | catalogued as rs776826529; called by muse, mutect2, varscan2
- MAGEC3 | c.330G>A p.G110= | Silent (SNP) | VAF 245/670 reads (37%) | catalogued as rs1189379264, COSV53576981, COSV71610157; called by muse, mutect2, varscan2
- MARCHF7 | c.2052C>T p.L684= | Silent (SNP) | VAF 146/388 reads (38%) | catalogued as rs748722727, COSV52027616, COSV52030677; called by muse, mutect2, varscan2
- MAST4 | c.7209G>A p.A2403= (on ENST00000403625 / NM_001164664.2; = p.A2214= on NM_015183.3) | Silent (SNP) | VAF 367/859 reads (43%) | catalogued as COSV55118427; called by muse, mutect2, varscan2
- MCCC1 | c.1791C>T p.Y597= | Silent (SNP) | VAF 130/405 reads (32%) | called by muse, mutect2, varscan2
- MROH2B | c.453C>T p.F151= | Silent (SNP) | VAF 177/426 reads (42%) | catalogued as COSV68180921; called by muse, mutect2, varscan2
- NEB | c.5595C>T p.S1865= | Silent (SNP) | VAF 156/502 reads (31%) | catalogued as rs1553485337; ClinVar: likely benign; called by muse, mutect2, varscan2
- NLRP1 | c.1363C>T p.L455= | Silent (SNP) | VAF 79/401 reads (20%) | called by muse, mutect2, varscan2
- NXNL1 | c.231C>T p.Y77= | Silent (SNP) | VAF 152/530 reads (29%) | catalogued as rs779258494, COSV57324283; called by muse, mutect2, varscan2
- OBSCN | c.14058G>C p.T4686= | Silent (SNP) | VAF 288/644 reads (45%) | catalogued as COSV52810645; called by muse, mutect2, varscan2
- OR10G4 | c.315C>T p.F105= | Silent (SNP) | VAF 125/354 reads (35%) | catalogued as COSV100305051; called by muse, mutect2, varscan2
- OR13C4 | c.342C>T p.L114= | Silent (SNP) | VAF 171/543 reads (31%) | catalogued as rs1207691866, COSV52925884; called by muse, mutect2, varscan2
- OR4D2 | c.753C>T p.F251= | Silent (SNP) | VAF 201/476 reads (42%) | catalogued as rs781540142, COSV73459786; called by muse, mutect2, varscan2
- OR51L1 | c.46C>T p.L16= | Silent (SNP) | VAF 116/378 reads (31%) | catalogued as COSV58625629; called by muse, mutect2, varscan2
- PDE6B | c.693C>T p.C231= | Silent (SNP) | VAF 181/583 reads (31%) | catalogued as rs1054222737, COSV55330407; called by muse, mutect2, varscan2
- PKHD1L1 | c.2403G>A p.T801= | Silent (SNP) | VAF 366/654 reads (56%) | catalogued as rs267601713, COSV65736382; called by muse, mutect2, varscan2
- PLA2G4F | c.1989C>T p.D663= | Silent (SNP) | VAF 21/478 reads (4%) | catalogued as rs369240112; called by muse, mutect2
- PRPS1L1 | c.903G>A p.R301= | Silent (SNP) | VAF 150/380 reads (39%) | catalogued as rs866960325, COSV72650009; called by muse, mutect2
- PRSS16 | c.1206C>T p.S402= | Silent (SNP) | VAF 168/718 reads (23%) | catalogued as COSV57915226; called by muse, mutect2, varscan2
- PYDC2 | c.207G>A p.G69= | Silent (SNP) | VAF 148/405 reads (37%) | catalogued as COSV72921321; called by muse, mutect2, varscan2
- QSER1 | c.315C>T p.S105= (on ENST00000399302; = p.S234= on NM_001076786.3) | Silent (SNP) | VAF 128/350 reads (37%) | called by muse, mutect2, varscan2
- RDH8 | c.354C>T p.P118= (on ENST00000651512; = p.P98= on NM_015725.4) | Silent (SNP) | VAF 132/423 reads (31%) | called by muse, mutect2, varscan2
- RSPRY1 | c.1497C>T p.F499= | Silent (SNP) | VAF 81/263 reads (31%) | catalogued as rs747506824; called by muse, mutect2, varscan2
- SALL1 | c.3879C>T p.P1293= | Silent (SNP) | VAF 143/488 reads (29%) | catalogued as COSV51764516; called by muse, mutect2, varscan2
- SGCZ | c.490C>T p.L164= | Silent (SNP) | VAF 114/366 reads (31%) | catalogued as COSV66016482; called by muse, mutect2, varscan2
- SH3TC1 | c.951G>A p.Q317= | Silent (SNP) | VAF 166/563 reads (29%) | catalogued as COSV55290767; called by muse, mutect2, varscan2
- SMARCA5 | c.1665C>T p.F555= | Silent (SNP) | VAF 150/462 reads (32%) | called by muse, mutect2, varscan2
- STAB1 | c.6510A>G p.G2170= | Silent (SNP) | VAF 194/582 reads (33%) | called by muse, mutect2, varscan2
- SUPT3H | c.504C>T p.D168= (on ENST00000371460 / NM_181356.3; = p.D157= on NM_003599.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 107/493 reads (22%) | catalogued as rs754207193, COSV60938906; called by muse, mutect2, varscan2
- TADA2B | c.763C>T p.L255= | Silent (SNP) | VAF 238/704 reads (34%) | catalogued as rs1261166853, COSV53828309; called by muse, mutect2, varscan2
- THOC1 | c.1266C>T p.F422= | Silent (SNP) | VAF 129/408 reads (32%) | called by muse, mutect2, varscan2
- TNFRSF10C | c.36C>T p.V12= | Silent (SNP) | VAF 219/647 reads (34%) | catalogued as rs1330365205; called by muse, mutect2, varscan2
- TRIOBP | c.1509C>T p.S503= | Silent (SNP) | VAF 212/745 reads (28%) | catalogued as rs758478434; called by muse, mutect2, varscan2
- UGT2A1 | c.885G>A p.Q295= | Silent (SNP) | VAF 93/294 reads (32%) | called by muse, mutect2, varscan2
- WDR72 | c.2136C>T p.V712= | Silent (SNP) | VAF 156/486 reads (32%) | catalogued as COSV100854456; called by muse, mutect2, varscan2
- WDR72 | c.1122C>T p.T374= | Silent (SNP) | VAF 71/217 reads (33%) | called by muse, mutect2, varscan2
- ZC3HAV1L | c.630C>T p.S210= | Silent (SNP) | VAF 572/698 reads (82%) | catalogued as rs772721759, COSV99312898, COSV99313026; called by muse, varscan2
- ZFYVE19 | c.1101C>T p.V367= (on ENST00000355341 / NM_001077268.2; = p.V357= on NM_032850.5) | Silent (SNP) | VAF 118/345 reads (34%) | called by muse, mutect2, varscan2
- ZNF181 | c.1231C>T p.L411= | Silent (SNP) | VAF 85/313 reads (27%) | called by muse, mutect2, varscan2
- C4orf50 | c.-110G>A | 5'UTR (SNP) | VAF 140/422 reads (33%) | catalogued as rs866327307; called by muse, mutect2, varscan2
- CNTN1 | c.1805-9436C>T | Intron (SNP) | VAF 130/327 reads (40%) | catalogued as COSV100751039; called by muse, mutect2, varscan2
- CPEB1 | c.-37C>T | 5'UTR (SNP) | VAF 138/475 reads (29%) | catalogued as rs996964265; called by muse, mutect2
- DAOA | c.282-60C>T | Intron (SNP) | VAF 78/286 reads (27%) | called by muse, mutect2
- KCNQ1 | c.1394-4305C>T | Intron (SNP) | VAF 109/287 reads (38%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+23061G>A | Intron (SNP) | VAF 192/508 reads (38%) | called by muse, mutect2
- NRSN1 | c.190-4450G>A | Intron (SNP) | VAF 237/536 reads (44%) | called by muse, mutect2, varscan2
- SEMA3B | c.922+50C>T | Intron (SNP) | VAF 172/458 reads (38%) | called by muse, mutect2, varscan2
- SILC1 | n.326A>G | RNA (SNP) | VAF 157/482 reads (33%) | called by muse, mutect2, varscan2
- SILC1 | n.327G>A | RNA (SNP) | VAF 159/483 reads (33%) | called by muse, mutect2, varscan2
- SLC35A2 | c.1163+129G>A | Intron (SNP) | VAF 210/602 reads (35%) | called by muse, mutect2, varscan2
- SPEF2 | c.4448-3931G>A | Intron (SNP) | VAF 163/368 reads (44%) | catalogued as rs527405217; called by muse, mutect2, varscan2
- WFDC2 | c.224-39C>T | Intron (SNP) | VAF 272/646 reads (42%) | catalogued as rs767689894, COSV54151927; called by muse, mutect2, varscan2
